Somatic mutation profile of tumor specimen TCGA-L5-A4OJ-01A (aliquot TCGA-L5-A4OJ-01A-11D-A27G-09) from TCGA case TCGA-L5-A4OJ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 70.2 years (25,657 days).
Specimen TCGA-L5-A4OJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8cf3ea7e-31b7-4f21-9832-2b1afb7b492d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A4OJ-11A (Solid Tissue Normal), aliquot TCGA-L5-A4OJ-11A-12D-A27G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86d17998-9b12-4b7a-934d-f7a372d5cb94

The open-access MAF lists 241 somatic variants for this specimen: 185 protein-altering or splice-affecting, 53 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 163, Silent 53, Nonsense Mutation 9, Frame Shift Ins 6, Frame Shift Del 4, 5'Flank 2, Splice Site 1, Splice Region 1, In Frame Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYRK1A | c.452dup p.N151Kfs*12 | Frame Shift Ins (INS) | VAF 5/23 reads (22%) | catalogued as rs797044523; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.758_760dup p.T253dup | In Frame Ins (INS) | VAF 73/195 reads (37%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- TP53 | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 144/416 reads (35%) | hotspot (GDC flag); catalogued as rs1567551854, COSV52678088, COSV52771688, COSV53175941; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRB1 | c.1808G>A p.R603Q | Missense Mutation (SNP) | VAF 25/36 reads (69%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.778); catalogued as rs555744616, COSV60098123; called by muse, mutect2, varscan2
- ALDH8A1 | c.1190C>T p.T397M | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs150799987; called by muse, varscan2
- ANAPC1 | c.1749C>A p.Y583* | Nonsense Mutation (SNP) | VAF 36/92 reads (39%) | catalogued as COSV100594946; called by muse, mutect2, varscan2
- APLNR | c.1023G>T p.E341D | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV57242621; called by muse, mutect2, varscan2
- ARID1A | c.4534C>T p.Q1512* | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | catalogued as COSV61373983; called by muse, mutect2, varscan2
- ASTN1 | c.3394C>T p.R1132W | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373152514, COSV62494292; called by muse, mutect2, varscan2
- ATP1A2 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs746478136, COSV100768050; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRWD3 | c.3286A>T p.K1096* | Nonsense Mutation (SNP) | VAF 19/42 reads (45%) | catalogued as COSV64745995; called by muse, mutect2, varscan2
- CBX6 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs779174067; called by muse, mutect2, varscan2
- CCNK | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs749729510, COSV66274837; called by muse, mutect2, varscan2
- CD1E | c.812C>A p.A271E | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1237493492; called by muse, mutect2, varscan2
- CD93 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1248609729, COSV55667078; called by muse, mutect2, varscan2
- CDH11 | c.1072T>G p.F358V | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as rs904356944; called by muse, mutect2, varscan2
- CDHR2 | c.1979G>A p.R660H | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as rs201340301, COSV99991564; called by muse, varscan2
- CECR2 | c.782G>A p.R261H (on ENST00000342247 / NM_001290047.2; = p.R98H on NM_001290046.1) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760539949, COSV52835916; called by muse, mutect2, varscan2
- CFAP221 | c.2290G>A p.E764K | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV54654365; called by muse, mutect2, varscan2
- CFHR5 | c.147A>C p.E49D | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0.05); PolyPhen benign (0.348); catalogued as COSV56823507, COSV56823864; called by muse, mutect2, varscan2
- CHIA | c.807C>A p.H269Q (on ENST00000343320; = p.H161Q on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.209); catalogued as rs773370727; called by muse, mutect2, varscan2
- CIB3 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs186929589, COSV54165957; called by muse, mutect2, varscan2
- CNTRL | c.1928G>A p.R643Q | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368951469; called by muse, mutect2, varscan2
- COL3A1 | c.2590G>T p.G864C | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100483764; called by muse, mutect2
- CPED1 | c.329C>A p.T110K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs564333233; called by muse, mutect2, varscan2
- CSRNP3 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs538593922; called by muse, mutect2, varscan2
- CTNNB1 | c.407T>C p.V136A | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated (0.16); PolyPhen benign (0.387); catalogued as COSV62722521; called by muse, mutect2, varscan2
- CYP2F1 | c.1183G>A p.V395I | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.511); catalogued as rs768113626, COSV100462602; called by muse, varscan2
- DENND4A | c.5224C>A p.H1742N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.075); catalogued as COSV71265562; called by muse, mutect2
- DNAH10 | c.3565G>T p.D1189Y (on ENST00000409039; = p.D1128Y on NM_207437.3) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV68988918; called by muse, mutect2, varscan2
- DNAH11 | c.10596G>T p.L3532F | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV60943161; called by muse, mutect2, varscan2
- DRD4 | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs377281442; called by muse, mutect2, varscan2
- EEF1A2 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.161); catalogued as rs1238718880; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM47C | c.1883C>T p.S628F | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100792260; called by muse, mutect2, varscan2
- FBN2 | c.5280G>T p.R1760S | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as rs886059898; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FFAR3 | c.754G>A p.G252S | Missense Mutation (SNP) | VAF 69/262 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.075); catalogued as rs540255880, COSV100588334; called by muse, mutect2, varscan2
- FMNL3 | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs745782905, COSV53302576; called by muse, mutect2, varscan2
- FOXK1 | c.1589C>T p.T530I | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.289); catalogued as rs1348063054; called by muse, mutect2, varscan2
- FRMD1 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as rs528646808, COSV51963519; called by muse, varscan2
- FSTL5 | c.416A>G p.K139R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV60183600, COSV60210915; called by muse, mutect2
- GABRA5 | c.1142A>G p.K381R | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs1401283864; called by muse, mutect2, varscan2
- GABRA5 | c.1257C>A p.Y419* | Nonsense Mutation (SNP) | VAF 12/20 reads (60%) | catalogued as rs747139454; called by muse, mutect2, varscan2
- HMCN1 | c.12612dup p.D4205Rfs*7 | Frame Shift Ins (INS) | VAF 24/48 reads (50%) | catalogued as rs765345975; called by mutect2, pindel, varscan2
- IFNA16 | c.140T>G p.I47S | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV66510144; called by muse, mutect2, varscan2
- JAG2 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1446530594, COSV59312707; called by muse, mutect2, varscan2
- JSRP1 | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs150323105; called by muse, mutect2, varscan2
- KIR2DL4 | c.155T>C p.L52P (on ENST00000396284; = p.L13P on NM_001080770.2) | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.926); catalogued as COSV60881614; called by muse, mutect2, varscan2
- LAMA1 | c.7651G>A p.G2551R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.131); catalogued as rs1335148467; called by muse, mutect2, varscan2
- LILRB5 | c.1487G>A p.R496H (on ENST00000449561 / NM_001081442.3; = p.R495H on NM_006840.5) | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs367690586; called by muse, mutect2, varscan2
- LRRK2 | c.2375G>T p.R792M | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.599); catalogued as COSV54149917; called by muse, mutect2, varscan2
- MAGEA10 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.07); catalogued as rs145553450, COSV54884254; called by muse, mutect2, varscan2
- MDGA1 | c.2557C>T p.R853W | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs752448153, COSV99777595; called by muse, varscan2
- MUC16 | c.37594T>C p.S12532P | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV67477981; called by muse, mutect2, varscan2
- MUC16 | c.13378T>A p.L4460M | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.644); catalogued as COSV67495851; called by muse, mutect2, varscan2
- NAP1L3 | c.154A>G p.S52G | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV59076071; called by muse, mutect2, varscan2
- NUAK1 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs757243977; called by muse, mutect2, varscan2
- OPCML | c.716A>C p.K239T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.017); catalogued as COSV59420469; called by muse, mutect2, varscan2
- OPRL1 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs760357145, COSV61091319; called by muse, mutect2, varscan2
- OR13C8 | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.404); catalogued as COSV58610926; called by muse, mutect2, varscan2
- OR4A47 | c.87C>A p.F29L | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.248); catalogued as COSV101487077; called by muse, mutect2, varscan2
- OTUD6A | c.715G>T p.D239Y | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV57972532; called by muse, mutect2, varscan2
- PCDHB3 | c.2320T>G p.F774V | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.013); catalogued as COSV50569640; called by muse, mutect2, varscan2
- PCDHB8 | c.977G>A p.G326E | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs782567447; called by muse, mutect2, varscan2
- PCLO | c.11074A>C p.S3692R | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV61630976; called by muse, mutect2, varscan2
- PGLYRP3 | c.530T>C p.V177A | Missense Mutation (SNP) | VAF 58/117 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1174208408; called by muse, mutect2, varscan2
- POMGNT2 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.781); catalogued as rs144487961; called by muse, mutect2, varscan2
- PPP1R3A | c.2678A>G p.D893G | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV52891449; called by mutect2, varscan2
- PRDM15 | c.2318G>A p.R773H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs376732864; called by muse, mutect2, varscan2
- PTGER3 | c.1067A>C p.K356T | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60691240; called by muse, mutect2, varscan2
- RANBP3 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.141); catalogued as rs564177004, COSV50381426; called by muse, mutect2, varscan2
- RBBP8 | c.2429G>T p.G810V | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59091014; called by muse, mutect2
- SERPINB9 | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs372377669; called by muse, mutect2, varscan2
- SHROOM2 | c.2266G>C p.A756P | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.913); catalogued as COSV101098186; called by muse, mutect2, varscan2
- SLC12A1 | c.1108T>G p.F370V | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.808); catalogued as COSV57709524; called by muse, mutect2, varscan2
- SLC25A22 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.767); catalogued as rs769329043; ClinVar: uncertain significance; called by muse, varscan2
- SLC9A7 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.474); catalogued as rs772862454; called by muse, varscan2
- SMCO4 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as rs202058974; called by muse, mutect2, varscan2
- SNTG1 | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs780973613, COSV52439193; called by muse, mutect2, varscan2
- SPATA31E1 | c.3917G>T p.R1306M | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57793550; called by muse, mutect2, varscan2
- SYDE2 | c.1161G>T p.L387F | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.467); catalogued as COSV52315970, COSV99320237; called by muse, mutect2, varscan2
- SYT16 | c.1499C>T p.S500L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1406155663; called by muse, mutect2, varscan2
- TAF1L | c.5417G>T p.R1806I | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as COSV54265834, COSV54266320; called by muse, mutect2, varscan2
- TARS2 | c.1046C>G p.S349C | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.855); catalogued as COSV64694850, COSV64696470; called by muse, mutect2, varscan2
- TICRR | c.2542C>G p.R848G | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99180328; called by muse, varscan2
- TMC4 | c.575G>A p.G192E (on ENST00000617472 / NM_001145303.3; = p.G186E on NM_144686.4) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1392176321, COSV99824687; called by muse, mutect2
- TOGARAM1 | c.4939G>C p.E1647Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100818321; called by muse, mutect2, varscan2
- TRAPPC8 | c.1326C>A p.C442* | Nonsense Mutation (SNP) | VAF 3/37 reads (8%) | catalogued as rs1225007063; called by muse, mutect2
- TTN | c.19489T>G p.F6497V (on ENST00000591111; = p.F5570V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/56 reads (39%) | PolyPhen benign (0.02); catalogued as rs1371961339, COSV100592117, COSV59896316; called by muse, mutect2, varscan2
- TTN | c.2506G>A p.G836S (on ENST00000591111; = p.G790S on NM_003319.4) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | PolyPhen probably damaging (0.962); catalogued as rs751157908, COSV59988553, COSV60007599; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBB2B | c.667G>A p.G223R | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.986); catalogued as COSV99455481; called by muse, mutect2, varscan2
- URB2 | c.3878C>T p.A1293V | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.293); catalogued as rs772780409; called by muse, mutect2, varscan2
- XIRP2 | c.1984G>T p.D662Y (on ENST00000628543; = p.D837Y on NM_152381.6) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99738183; called by muse, mutect2, varscan2
- XKR4 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.042); catalogued as rs762821952, COSV100533271; called by muse, mutect2, varscan2
- ZNF254 | c.938A>G p.K313R | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as rs760652801; called by muse, mutect2, varscan2
- ZNF257 | c.91G>T p.D31Y | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs986908819, COSV71311173; called by muse, mutect2, varscan2
- ZNF438 | c.1385G>A p.G462E | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs1442966925; called by muse, mutect2, varscan2
- ALPK2 | c.4123G>C p.D1375H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- ARAF | c.803A>C p.K268T | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.52); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ARHGAP29 | c.1985T>G p.L662R | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGEF12 | c.2207C>T p.T736I | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- ASB12 | c.932T>G p.I311S | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- BRWD3 | c.4226A>G p.K1409R | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.99); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- C19orf44 | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.221); called by muse, varscan2
- C2orf80 | c.366+1G>A p.X122_splice | Splice Site (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
- CAVIN1 | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CDH6 | c.134A>C p.K45T | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- CIP2A | c.1249G>T p.A417S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.95); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CMYA5 | c.2552_2555dup p.E853Ifs*2 | Frame Shift Ins (INS) | VAF 16/25 reads (64%) | called by mutect2, pindel, varscan2
- CNTLN | c.282dup p.E95Rfs*28 | Frame Shift Ins (INS) | VAF 7/34 reads (21%) | called by mutect2, pindel
- CNTN1 | c.227A>C p.K76T | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- COL11A1 | c.1757G>C p.G586A | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CWF19L2 | c.796C>T p.Q266* | Nonsense Mutation (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- DCLK1 | c.1768A>C p.S590R | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- DDX17 | c.656C>G p.S219C | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DHX8 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- EPB41L3 | c.2590G>A p.V864M | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- FAT4 | c.10523A>C p.N3508T | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FATE1 | c.5C>A p.A2E | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- FGF13 | c.658A>C p.S220R | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FUT2 | c.838_839del p.Q280Vfs*2 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | called by pindel, varscan2
- FZD9 | c.1544T>C p.F515S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); called by muse, mutect2
- GABRA2 | c.1133T>C p.L378P | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPR155 | c.1159A>C p.S387R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- HACL1 | c.1295T>G p.F432C | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HIP1 | c.2564C>A p.T855K | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.149); called by muse, mutect2
- HUWE1 | c.10103G>A p.G3368D | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.52); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- HUWE1 | c.661C>A p.L221I | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- ICA1L | c.53G>A p.R18K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.98); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- IL13RA2 | c.941T>G p.I314S | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IL27 | c.191A>G p.Q64R | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.107); called by muse, mutect2
- ILDR2 | c.1036G>T p.D346Y | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- ITGA10 | c.3121A>G p.S1041G | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- KDM5A | c.2932_2938del p.V978Kfs*15 | Frame Shift Del (DEL) | VAF 24/73 reads (33%) | called by mutect2, pindel, varscan2
- KIAA0319 | c.3134A>T p.K1045M | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- KRTAP10-7 | c.769A>C p.T257P | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- KRTAP12-3 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LCOR | c.1172G>T p.G391V | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LPAR1 | c.170T>A p.I57N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- LRFN1 | c.1556G>A p.G519E | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- LRRC8C | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LRRTM4 | c.886A>G p.T296A | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MAP3K21 | c.1715_1716del p.T572Sfs*8 | Frame Shift Del (DEL) | VAF 18/36 reads (50%) | called by pindel, varscan2
- MFAP1 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- MID1 | c.1151C>A p.P384H | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); called by muse, mutect2
- MID2 | c.1177C>A p.L393I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- MIPOL1 | c.551G>C p.R184T | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC17 | c.2809G>C p.V937L | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOX4 | c.191T>C p.L64P | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- OR2M2 | c.28T>G p.S10A | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- OR2T6 | c.800C>T p.T267I | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- OR52H1 | c.866T>C p.L289P (on ENST00000322653; = p.L295P on NM_001005289.1) | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- OTUD4 | c.1634C>T p.S545L (on ENST00000447906 / NM_001366057.1; = p.S480L on NM_001102653.1) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- PAK6 | c.1873C>T p.H625Y | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHA12 | c.2101A>G p.I701V | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- PDK1 | c.246G>T p.E82D | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PPP4R4 | c.996G>T p.Q332H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- RANBP6 | c.2198A>C p.E733A | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- RP1L1 | c.6382G>A p.E2128K | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.57); called by muse, mutect2
- RPL10L | c.44A>G p.K15R | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SALL1 | c.1724C>A p.P575Q | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SCNN1G | c.1447G>T p.V483F | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2
- SEC11C | c.536dup p.L179Ffs*13 | Frame Shift Ins (INS) | VAF 20/60 reads (33%) | called by mutect2, pindel, varscan2
- SERF2 | c.6C>T p.T2= | Splice Region (SNP) | VAF 13/41 reads (32%) | called by muse, mutect2, varscan2
- SERPINA6 | c.765G>T p.M255I | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- SF3B4 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- SH3PXD2A | c.2170T>C p.S724P (on ENST00000369774 / NM_001365079.1; = p.S696P on NM_014631.2) | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- SLC12A1 | c.61T>C p.F21L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- SLCO4C1 | c.1746C>A p.C582* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- SPAG6 | c.1230dup p.C411Mfs*8 | Frame Shift Ins (INS) | VAF 14/37 reads (38%) | called by mutect2, pindel, varscan2
- SPATA22 | c.872A>G p.N291S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SPON1 | c.2291C>T p.S764L | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- STON1 | c.1129A>C p.K377Q | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYNE1 | c.5767G>T p.A1923S (on ENST00000367255 / NM_182961.4; = p.A1930S on NM_033071.3) | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.156); called by muse, mutect2
- SYNE1 | c.5436A>C p.E1812D (on ENST00000367255 / NM_182961.4; = p.E1819D on NM_033071.3) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.554); called by muse, varscan2
- TDRD10 | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 28/117 reads (24%) | called by muse, mutect2, varscan2
- THSD7B | c.3230A>G p.E1077G (on ENST00000272643; = p.E1075G on NM_001316349.2) | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TOX | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- TP53 | c.921_925del p.L308Qfs*27 | Frame Shift Del (DEL) | VAF 96/306 reads (31%) | called by mutect2, pindel, varscan2
- TRPM7 | c.4594C>T p.P1532S | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- UGT2B11 | c.76G>T p.V26L | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- WDR48 | c.1592G>T p.R531L | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.461); called by muse, mutect2
- ZKSCAN5 | c.823G>T p.D275Y | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- ZNF75D | c.157T>G p.W53G | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ZNF804A | c.2013A>C p.E671D | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF804B | c.4027A>C p.N1343H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ANKRD44 | c.768C>T p.N256= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as rs560770318, COSV56563629; called by muse, mutect2, varscan2
- AP5S1 | c.357G>T p.S119= | Silent (SNP) | VAF 17/51 reads (33%) | called by muse, mutect2, varscan2
- APBA3 | c.1113G>A p.P371= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs1302348869; called by muse, mutect2, varscan2
- BICD2 | c.918C>T p.G306= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as rs540280844; ClinVar: likely benign; called by muse, mutect2, varscan2
- CACNB1 | c.576C>A p.S192= | Silent (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- CAND2 | c.2424G>A p.V808= (on ENST00000456430 / NM_001162499.2; = p.V715= on NM_012298.3) | Silent (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- CCDC170 | c.63T>G p.T21= | Silent (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- CNTN5 | c.1647C>T p.Y549= | Silent (SNP) | VAF 25/45 reads (56%) | catalogued as rs201116802, COSV54361482, COSV54370732; called by muse, mutect2, varscan2
- DOCK4 | c.5580G>A p.S1860= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs747119054, COSV101447833; called by muse, mutect2, varscan2
- EFCAB5 | c.330A>G p.P110= | Silent (SNP) | VAF 6/10 reads (60%) | called by muse, varscan2
- EGLN2 | c.120G>T p.L40= | Silent (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2, varscan2
- ELFN2 | c.1080C>T p.C360= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as rs762489188, COSV68744115; called by muse, mutect2, varscan2
- ERBB4 | c.3426A>G p.R1142= | Silent (SNP) | VAF 45/107 reads (42%) | called by muse, mutect2, varscan2
- FAM163A | c.408C>T p.S136= | Silent (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2, varscan2
- FAM186B | c.1596G>T p.R532= | Silent (SNP) | VAF 16/51 reads (31%) | called by muse, mutect2, varscan2
- FAT1 | c.1863G>A p.S621= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs551785621; called by muse, mutect2, varscan2
- FCGBP | c.10698G>A p.S3566= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs143346927; called by muse, mutect2, varscan2
- FSHR | c.747T>G p.T249= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV58616802; called by muse, mutect2, varscan2
- GRIK5 | c.1779C>A p.G593= | Silent (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- HSD17B12 | c.201A>G p.A67= | Silent (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- KLHL32 | c.690C>T p.Y230= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as rs1195222914; called by muse, mutect2, varscan2
- LBX1 | c.18C>T p.D6= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs772676696; called by muse, mutect2, varscan2
- LMX1B | c.627C>T p.S209= | Silent (SNP) | VAF 23/40 reads (58%) | catalogued as rs780090833, COSV100826934; called by muse, mutect2, varscan2
- LY75 | c.3633C>T p.C1211= | Silent (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
- MDGA1 | c.225G>A p.T75= | Silent (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2, varscan2
- MOB3B | c.216C>T p.N72= | Silent (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- NTRK3 | c.129C>T p.I43= | Silent (SNP) | VAF 12/51 reads (24%) | called by muse, mutect2, varscan2
- OR6N1 | c.576G>A p.T192= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs757996854; called by muse, varscan2
- OTOGL | c.6030T>G p.S2010= (on ENST00000547103; = p.S2001= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 41/68 reads (60%) | called by muse, mutect2, varscan2
- PACS2 | c.1644C>T p.P548= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs782154081, COSV100331041; called by muse, mutect2, varscan2
- PHEX | c.1356A>G p.K452= | Silent (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- PHOSPHO1 | c.789G>T p.V263= | Silent (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- PITPNM2 | c.369C>T p.P123= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as rs776857510, COSV54904438; called by muse, mutect2, varscan2
- PKHD1 | c.8424C>T p.G2808= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs181741077; called by muse, mutect2, varscan2
- PRRG3 | c.633T>G p.S211= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as COSV64851052; called by muse, mutect2, varscan2
- RHOXF2 | c.465C>T p.R155= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as rs1556004657, COSV101002773; called by muse, mutect2, varscan2
- RIBC1 | c.693T>C p.C231= | Silent (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
- RTL3 | c.996C>A p.L332= | Silent (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- SBNO1 | c.393C>T p.R131= (on ENST00000420886; = p.R130= on NM_018183.5) | Silent (SNP) | VAF 37/95 reads (39%) | called by muse, mutect2, varscan2
- SLC4A1AP | c.345G>A p.E115= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as rs140696526; called by muse, mutect2, varscan2
- SLC9A6 | c.1923C>T p.V641= | Silent (SNP) | VAF 21/60 reads (35%) | called by muse, mutect2, varscan2
- SRRM4 | c.1563G>T p.R521= | Silent (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- TAS1R3 | c.2112G>A p.P704= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs746013207; called by muse, mutect2, varscan2
- TENM1 | c.7707G>T p.G2569= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV100951180; called by muse, mutect2, varscan2
- TFAP2D | c.372G>A p.S124= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as rs760105430, COSV50408164, COSV50450145; called by muse, mutect2, varscan2
- TPO | c.759C>T p.F253= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs757051221, COSV61100942; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRHDE | c.2013T>A p.T671= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV53830606; called by muse, mutect2, varscan2
- TWIST1 | c.411G>A p.T137= | Silent (SNP) | VAF 16/29 reads (55%) | called by muse, mutect2, varscan2
- TXNDC2 | c.609G>A p.Q203= (on ENST00000306084 / NM_001098529.2; = p.Q136= on NM_032243.6) | Silent (SNP) | VAF 11/46 reads (24%) | called by muse, mutect2, varscan2
- VAC14 | c.411C>T p.D137= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs151275776; called by muse, mutect2, varscan2
- VPS4B | c.915C>T p.A305= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV53069433; called by muse, mutect2, varscan2
- WIPF1 | c.621C>T p.P207= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs757610387; called by muse, varscan2
- ZNF649 | c.543T>C p.T181= | Silent (SNP) | VAF 44/132 reads (33%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849748 A>G | 5'Flank (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- ARHGAP28 | c.2030+1892A>G | Intron (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- SLC5A1 | chr22:32039529 G>A | 5'Flank (SNP) | VAF 41/85 reads (48%) | catalogued as rs199843705; called by muse, mutect2, varscan2
